Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GH-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Background melanoma, (L) axillary mass (L) axillary dissection specimen. primary back 0.8mm.
Note: This specimen has been sampled for tumour banking.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking

MACROSCOPIC DESCRIPTION

(Dr.

"LEFT AXILLARY CONTENTS (FRESH)". An irregular mass of fatty tissue, 170 x 100 x 45mm with an attached portion of skeletal muscle 75 x 50 x 25mm. There is a pale nodule located about 20mm from the attachment of the skeletal muscle measuring 40 x 35 x 32mm. No orientation is present. Lymph node serially dissected from one side to the other.

- A. Four lymph nodes.
- B. ?Three lymph nodes.
- C. Three lymph nodes.
- D. ?Four lymph nodes.
- E. Three lymph nodes.
- F. One lymph node bisected.
- G. Full face of nodule sampled for tumour banking including resection margin.
- H. Three lymph nodes.
- J. ?Three lymph nodes.
- K. Two lymph nodes.
- L. ? two lymph nodes.
- M. One lymph node bisected.
- N. Four lymph nodes.
- P. Three lymph nodes.
- Q. One lymph node bisected.
- R & S. Each four lymph nodes.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axilla C77.3

bw 4/10/11

MICROSCOPIC REPORT

"LEFT AXILLARY CONTENTS (FRESH)". The largest nodule, probably an enlarged lymph node (1G), is virtually replaced by an epithelioid non-pigmented malignant neoplasm consistent with metastatic melanoma. There is no convincing extra nodal spread. The remaining forty two lymph nodes show no evidence of malignancy.

Positive: S100+++, HMB45+++.

Reviewed Initials:	6/23/11	6/23/11

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

SUMMARY

Lymph nodes left axilla - Metastatic melanoma (1/43)

REPORTED BY: Prof.

Source: NCI Genomic Data Commons file c1ab09b2-1b67-4771-9743-ab0b72b82802 (TCGA-EE-A2GH.4FF6F797-FFBC-4C27-8195-3A7F36B2D8AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).